Surgical pathology report (de-identified scan), TCGA case TCGA-K4-A3WU, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-K4-A3WU-01B (Primary Tumor).

[page 1 of 5]
Name

Encounter Number

COPY ONLY DO NOT FILE

x

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Results

Final

Source of Specimen

- A. RIGHT DISTAL URETER - FS (MARGIN INKED)-
- B. LEFT DISTAL URETER - FS (MARGIN INKED)-
- C. BLADDER, PROSTATE, AND SEMINAL VESICLES (SEE PATH SHEET)-
- D. RIGHT PELVIC LYMPH NODES-
- E. LEFT PELVIC LYMPH NODES-

ICD-O-3

Carcinoma, urothelial, NOS
8120/3Site: bladder, NOS
C67.9 5-11-12
RO

FINAL DIAGNOSIS:

- A. RIGHT DISTAL URETER - FS (MARGIN INKED)-
NO CARCINOMA SEEN.
- B. LEFT DISTAL URETER - FS (MARGIN INKED)-
NO CARCINOMA SEEN.
- C. BLADDER, PROSTATE, AND SEMINAL VESICLES (SEE PATH SHEET)-
INVASIVE CARCINOMA, HIGH GRADE.

TUMOR SITE: RIGHT BASE, URINARY BLADDER.

HISTOLOGIC TYPE: UROTHELIAL.

SQUAMOUS DIFFERENTIATION: NOT PRESENT.

GLANDULAR DIFFERENTIATION: NOT PRESENT.

TUMOR SIZE: 2.3 CM.

HISTOLOGIC GRADE: 3/3.

EXTRAVESICULAR MASS: MICROSCOPICALLY PRESENT.

Prepared for C

[page 2 of 5]
DIRECT INVASION OF PROSTATIC STROMA: PRESENT.

INVASION OF SEMINAL VESICLE: NOT PRESENT.

INVASION OF PELVIC OR ABDOMINAL WALL: NOT PRESENT.

SPECIMEN TYPE: RADICAL CYSTOPROSTATECTOMY

TNM STAGE: pT4a, pN0, pMX.

LYMPH NODE(S) INCLUDED IN ALL PARTS: NUMBER INVOLVED : 0
NUMBER EXAMINED: 5

LYMPHATIC (SMALL VESSEL) INVASION: SEEN.

ASSOCIATED EPITHELIAL LESIONS: UROTHELIAL CARCINOMA IN SITU
IDENTIFIED.

NO TUMOR SEEN AT MARGINS.

ADENOCARCINOMA OF PROSTATE. NO EXTRAPROSTATIC EXTENSION SEEN.

TUMOR SITE: POSTERIOR , MOSTLY IN PERIPHERAL ZONE.

SPECIMEN TYPE: RADICAL CYSTOPROSTATECTOMY.

SIZE: 4 x 6 x 4 CM.

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 3 + 3 = 6/10.

SEVERITY IN EXTENT OF TUMOR: 1 /5.

DOMINANT NODULE (AT LEAST 1 CM IN SIZE): NOT PRESENT.

TREATMENT EFFECT ON CARCINOMA: NOT IDENTIFIED.

TNM STAGE: pT3a, pN0, pMX.

LYMPHATIC (SMALL VESSEL) INVASION: NOT SEEN.

PERINEURAL INVASION: NOT PRESENT.

NO TUMOR SEEN IN SEMINAL VESICLES.

NO TUMOR SEEN AT SPECIMEN MARGINS.

D. RIGHT PELVIC LYMPH NODES-

NO CARCINOMA SEEN IN FIVE LYMPH NODES (0/5).

E. LEFT PELVIC LYMPH NODES-

Prepared for:

[page 3 of 5]
MATURE ADIPOSE TISSUE WITH RARE LYMPHOID AGGREGATES. NO
WELL-DEFINED LYMPH NODES SEEN.

Signed Others

Frozen Section

A. RIGHT DISTAL URETER MARGIN: NO TUMOR SEEN.

LEFT DISTAL URETER MARGIN: NO TUMOR SEEN.

Case Clinical Information

BLADDER CANCER

Gross Description

A. Received in formalin labeled with the patient's name and "right distal ureter" are two fatty tissues measuring 4 and 9 mm in greatest dimensions. The specimen is totally submitted in A1.

B. Received in formalin labeled with the patient's name and "left distal ureter" are two fibrofatty tissues measuring 12 and 11 mm in greatest dimensions, respectively. The specimen is totally submitted in B1.

C. Received in formalin labeled with the patient's name and "bladder, prostate, and seminal vesicles" is a specimen so designated. The specimen overall measures 14 cm superior to inferior. The included prostate measures 4 cm superior to inferior, 6 cm right to left, 4 cm anterior to posterior. The bladder cavity appears somewhat contracted, measuring 2.5 cm superior to inferior, 2 cm right to left, 2 cm anterior to posterior. The bladder mucosa appears edematous and congested. There is an apparent area of induration and ulceration measuring 1.5 cm midline posterior bladder base. The right and left vas deferens track along the posterior bladder wall 4.5 cm on the right, 5 cm on the left. The right side of the specimen previously has been inked blue and the left side black. The specimen reveals numerous staple lines. The left and right ureters are identified with the left ureter deeply retracted,

Prepared.

[page 4 of 5]
the right ureter more superficially so and with apparent induration surrounding the right ureteral stub. The right seminal vesicle measures 4 x 1.5 x 1 cm. The left measures 4 x 1.5 x 1.5 cm in greatest dimensions. Tissue surrounding the inferior prostate/urethral junction is somewhat disrupted.

Section code: C1-shaved left vas resection margin and deeply retracted left ureter; C2-shaved right vas margin and retracted right ureter; C3=left seminal vesicle; C4=right seminal vesicle; C5-shaved distal prostate surgical margin; C6-C8=posterior mid prostate sampled; C9-C13=posterior superior prostate sample; C14-C19=left lateral bladder base extensively sampled proceeding inferior to superior; C20-C25=right lateral bladder base extensively sampled proceeding inferior to superior.

D. Received in formalin labeled with the patient's name and "right pelvic lymph nodes" is irregular fragment of fibroadipose tissue measuring 3.5 x 1.5 x 1 cm. There is a dominant area of induration, which may represent a fatty lymph node. Bisected and submitted totally in D1-D2, additional subtle areas of induration in D3.

E. Received in formalin labeled with the patient's name and "left pelvic lymph nodes" is an irregular fragment of fibroadipose tissue measuring 3 x 1.5 x 1 cm. A lymph node is not appreciated definitely. The entire specimen is submitted in E1-E3.

Procedure

- A. AA ROUTINE H&E X1 BLOCK
H&E X1
- B. AA ROUTINE H&E X1 BLOCK
H&E X1
- C. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- C. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- C. AA ROUTINE H&E X1 BLOCK.3
H&E X1
- C. AA ROUTINE H&E X1 BLOCK.4
H&E X1
- C. AA ROUTINE H&E X1 BLOCK.5
H&E X1 A RECUTS
- C. AA ROUTINE H&E X1 BLOCK.6
H&E X1
- C. AA ROUTINE H&E X1 BLOCK.7
H&E X1
- C. AA ROUTINE H&E X1 BLOCK.8
H&E X1

Prepared for

[page 5 of 5]
C. AA ROUTINE H&E X1 BLOCK.9
H&E X1
C. AA ROUTINE H&E X1 BLOCK.10
H&E X1
C. AA ROUTINE H&E X1 BLOCK.11
H&E X1

C. AA ROUTINE H&E X1 BLOCK.12
H&E X1
C. AA ROUTINE H&E X1 BLOCK.13
H&E X1
C. AA ROUTINE H&E X1 BLOCK.14
H&E X1
C. AA ROUTINE H&E X1 BLOCK.15
H&E X1
C. AA ROUTINE H&E X1 BLOCK.16
H&E X1
C. AA ROUTINE H&E X1 BLOCK.17
H&E X1
C. AA ROUTINE H&E X1 BLOCK.18
H&E X1
C. AA ROUTINE H&E X1 BLOCK.19
H&E X1
C. AA ROUTINE H&E X1 BLOCK.20
H&E X1
C. AA ROUTINE H&E X1 BLOCK.21
H&E X1
C. AA ROUTINE H&E X1 BLOCK.22
H&E X1
C. AA ROUTINE H&E X1 BLOCK.23
H&E X1
C. AA ROUTINE H&E X1 BLOCK.24
H&E X1
C. AA ROUTINE H&E X1 BLOCK.25
H&E X1
D. AA ROUTINE H&E X1 BLOCK.1
H&E X1
D. AA ROUTINE H&E X1 BLOCK.2
H&E X1
D. AA ROUTINE H&E X1 BLOCK.3
H&E X1
E. AA ROUTINE H&E X1 BLOCK.1
H&E X1
E. AA ROUTINE H&E X1 BLOCK.2
H&E X1
E. AA ROUTINE H&E X1 BLOCK.3
H&E X1

Source: NCI Genomic Data Commons file 5dedfb03-6ab6-448c-bfe3-de186f5b77f2 (TCGA-K4-A3WU.57551F09-2ACE-481D-99A0-53A0E7814F70.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).